Gene-level copy-number profile of tumor specimen TCGA-CR-7390-01A from TCGA case TCGA-CR-7390, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.3 years (24,575 days).
Specimen TCGA-CR-7390-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.bb800f0a-82e0-46fc-87b1-27f33b4cdbe6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7390-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b76e7d9-a1dc-4d5b-890e-34281afa036d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,242; copy number 2: 9,422; copy number 3: 22,581; copy number 4: 17,821; copy number 5: 1,639; copy number 6: 4,705; copy number 7: 1,280; copy number 8: 543; copy number 9: 57; copy number 10: 178; copy number 11: 17; copy number 12: 23; copy number 14: 150; copy number 15: 3; copy number 19: 112; copy number 29: 39; copy number 32: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7390-01A-11D-2010-01): tumor purity 0.47, ploidy 3.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,403 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:94,725,674–97,995,948, 138 genes, copy number 10 (broad region; genes not listed).
- chr2:121,040,610–121,809,962, 17 genes, copy number 11: Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823.
- chr2:172,084,740–177,559,299, 126 genes, copy number 14 (within-gene range 3–14) (broad region; genes not listed).
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 7–14 (broad region; genes not listed).
- chr8:31,639,222–41,896,762, 175 genes, copy number 12–32 (within-gene range 2–32) (broad region; genes not listed).
- chr12:32,985,838–34,249,958, 20 genes, copy number 7: ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr12:62,139,999–64,162,217, 43 genes, copy number 10–15 (within-gene range 6–15): AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2.
- chr19:34,733,298–35,758,079, 82 genes, copy number 7–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 74. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
